Somatic mutation profile of tumor specimen TARGET-30-PATGWT-01A (aliquot TARGET-30-PATGWT-01A-01D) from TARGET case TARGET-30-PATGWT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.6 years (591 days).
Specimen TARGET-30-PATGWT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3141f3b9-f4bf-44a1-a1af-eb70ac27e021.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATGWT-10A (Blood Derived Normal), aliquot TARGET-30-PATGWT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/824b86ca-488f-45fe-9f34-ce56583de63b

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 44/98 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP10B | c.2179C>A p.L727M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59146220; called by muse, mutect2, varscan2
- CD163 | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as rs1279399354, COSV63130594; called by muse, mutect2, varscan2
- GPC2 | c.1021C>A p.Q341K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52784485; called by muse, mutect2, varscan2
- HSPA4 | c.108-1G>T p.X36_splice | Splice Site (SNP) | VAF 24/82 reads (29%) | catalogued as COSV59181828; called by muse, mutect2, varscan2
- LRRC19 | c.698C>A p.S233* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV66259333, COSV66259379; called by muse, mutect2, varscan2
- MGAT1 | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | PolyPhen benign (0); catalogued as COSV57133280; called by muse, mutect2, varscan2
- NEDD9 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65219541, COSV65219910; called by muse, mutect2, varscan2
- PICALM | c.1099G>T p.G367W | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV62669703; called by muse, mutect2, varscan2
- PIK3R5 | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52651484; called by muse, mutect2, varscan2
- TTC7A | c.1641G>T p.Q547H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55409521; called by muse, mutect2, varscan2
- CAPNS1 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by muse, mutect2
- LRP2 | c.7548C>A p.P2516= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as COSV55545397; called by muse, mutect2, varscan2
